Somatic mutation profile of tumor specimen ALCH-B21W-TTP1-A (aliquot ALCH-B21W-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B21W, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.1 years (20,869 days).
Specimen ALCH-B21W-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6365eff-5b6d-4507-9aa4-3a973c761da2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B21W-NB1-A (Blood Derived Normal), aliquot ALCH-B21W-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ef7fffa-4b50-4ae8-a95c-f8f6453a307a

The open-access MAF lists 906 somatic variants for this specimen: 620 protein-altering or splice-affecting, 176 silent, 110 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 515, Silent 176, Intron 54, Nonsense Mutation 49, Frame Shift Del 26, Splice Site 19, RNA 18, 5'UTR 15, 3'UTR 12, 5'Flank 9, Splice Region 5, Frame Shift Ins 3.

Variants (750 of 906; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 176/377 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLP1 | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 52/415 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398123466, CM002833, COSV58275944; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 325/544 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.70-1G>T p.X24_splice | Splice Site (SNP) | VAF 77/331 reads (23%) | catalogued as rs1295724229; called by muse, mutect2, varscan2
- ABCB5 | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51721056; called by muse, mutect2, varscan2
- ABCD4 | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV53994431; called by muse, mutect2, varscan2
- ACSM5 | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771749222; called by muse, mutect2, varscan2
- ADAMTS20 | c.2411C>G p.A804G | Missense Mutation (SNP) | VAF 93/188 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.06); catalogued as COSV101166377; called by muse, mutect2, varscan2
- ADGRG2 | c.1974G>T p.R658S (on ENST00000379869 / NM_001079858.3; = p.R655S on NM_005756.4) | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100491833; called by muse, mutect2, varscan2
- AFF3 | c.1913G>T p.R638L | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57839785; called by muse, mutect2, varscan2
- AGPAT4 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs9458138; called by muse, mutect2, varscan2
- ANKRD30B | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV62815462; called by muse, mutect2, varscan2
- ANKRD6 | c.1760G>A p.R587Q (on ENST00000339746 / NM_001242809.2; = p.R582Q on NM_014942.4) | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as rs778483690, CM150859, COSV60231051; called by muse, mutect2, varscan2
- ANKS1B | c.2613G>T p.Q871H (on ENST00000547776 / NM_152788.4; = p.Q97H on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as rs756721207; called by muse, mutect2, varscan2
- AR | c.2119G>C p.E707Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV65952965; called by muse, mutect2
- ARHGAP15 | c.1280C>G p.T427R | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV54483751; called by muse, mutect2, varscan2
- ARHGEF9 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99491343; called by muse, mutect2, varscan2
- ASH2L | c.1804G>A p.V602M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs1361494433; called by muse, mutect2, varscan2
- B3GAT2 | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759422862; called by muse, mutect2, varscan2
- BCAN | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); catalogued as rs759486942, COSV61257438; called by muse, mutect2, varscan2
- BCOR | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 93/493 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs960778355, COSV60699113; called by muse, mutect2, varscan2
- BPIFB1 | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); catalogued as rs781028806; called by muse, mutect2, varscan2
- BRINP2 | c.2274G>T p.R758S | Missense Mutation (SNP) | VAF 134/297 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV64175680; called by muse, mutect2, varscan2
- C4orf54 | c.1492C>A p.P498T | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.085); catalogued as rs1191272330; called by muse, mutect2, varscan2
- C9orf135 | c.665del p.T222Ifs*13 | Frame Shift Del (DEL) | VAF 18/112 reads (16%) | catalogued as COSV101019885; called by mutect2, pindel
- CACNA1B | c.939G>T p.M313I | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99497973; called by muse, mutect2, varscan2
- CACNA1E | c.2277G>A p.W759* | Nonsense Mutation (SNP) | VAF 56/524 reads (11%) | catalogued as COSV62384876; called by muse, mutect2
- CACNA2D4 | c.2302A>T p.R768* | Nonsense Mutation (SNP) | VAF 131/243 reads (54%) | catalogued as rs1555181367; called by muse, mutect2, varscan2
- CADM4 | c.940G>T p.V314L | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.087); catalogued as COSV99731375; called by muse, mutect2, varscan2
- CAPN6 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60696883; called by muse, mutect2, varscan2
- CCDC144A | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.908); catalogued as rs988812974; called by mutect2, varscan2
- CCNA1 | c.850G>T p.G284W | Missense Mutation (SNP) | VAF 57/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55221261; called by muse, mutect2, varscan2
- CD34 | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 144/281 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777117210, COSV60412407; called by muse, mutect2, varscan2
- CDH11 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99217522; called by muse, mutect2
- CEMIP2 | c.2515G>A p.G839S | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1156285025; called by muse, mutect2, varscan2
- CFAP53 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV101275062; called by muse, mutect2, varscan2
- CKAP5 | c.2015G>A p.G672E | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV56374285; called by muse, mutect2, varscan2
- CNTLN | c.2120G>T p.R707M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as rs1222075483; called by muse, mutect2, varscan2
- CRAT | c.495del p.K166Sfs*5 | Frame Shift Del (DEL) | VAF 54/151 reads (36%) | catalogued as rs772054700, COSV58879005; called by mutect2, pindel, varscan2
- CRISP1 | c.632G>T p.C211F | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59992745, COSV59994803; called by muse, varscan2
- CSMD2 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV53926085, COSV53941655; called by muse, mutect2, varscan2
- CT47B1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 84/431 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as rs1236650153; called by muse, mutect2, varscan2
- CTNNA2 | c.1673T>C p.M558T | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760685287, COSV100559647; called by muse, mutect2, varscan2
- CUBN | c.7001-2A>T p.X2334_splice | Splice Site (SNP) | VAF 54/534 reads (10%) | catalogued as COSV64729057; called by muse, mutect2, varscan2
- CUBN | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 127/430 reads (30%) | catalogued as COSV64722202; called by muse, mutect2, varscan2
- CXCL3 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV56017603; called by muse, mutect2, varscan2
- DCAF4L2 | c.130C>A p.R44S | Missense Mutation (SNP) | VAF 80/682 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV60476978, COSV60484022; called by muse, mutect2, varscan2
- DCBLD2 | c.1862A>G p.Y621C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766248684, COSV54581058; called by muse, varscan2
- DCLK1 | c.1015G>T p.G339* | Nonsense Mutation (SNP) | VAF 18/130 reads (14%) | catalogued as COSV55173646; called by muse, mutect2, varscan2
- DDX25 | c.1130G>C p.R377P | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754292550; called by muse, mutect2, varscan2
- DEFB118 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 116/476 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770422931; called by muse, mutect2, varscan2
- DHX38 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV51698355; called by muse, mutect2, varscan2
- DISC1 | c.1793-2A>T p.X598_splice | Splice Site (SNP) | VAF 142/635 reads (22%) | catalogued as COSV54410846; called by muse, mutect2, varscan2
- DMRT2 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 58/506 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs758428225; called by muse, mutect2, varscan2
- DNAH8 | c.10499C>T p.T3500I | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs1259894906; called by muse, mutect2, varscan2
- DNAH9 | c.4805C>A p.P1602Q | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52361896; called by muse, mutect2
- DNMT3L | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs745742350, COSV54264938; called by muse, mutect2, varscan2
- DSG4 | c.2611C>T p.L871F | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.07); catalogued as COSV100355633; called by muse, mutect2, varscan2
- EOMES | c.284T>A p.V95E | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); catalogued as rs1348612478; called by muse, mutect2, varscan2
- EPS15 | c.2472T>A p.C824* | Nonsense Mutation (SNP) | VAF 39/178 reads (22%) | catalogued as COSV65541114; called by muse, mutect2, varscan2
- F5 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 69/568 reads (12%) | catalogued as COSV63123152; called by muse, mutect2, varscan2
- FAM120C | c.2739T>G p.F913L | Missense Mutation (SNP) | VAF 62/408 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.014); catalogued as COSV100070231; called by muse, mutect2
- FAT3 | c.7463G>T p.G2488V | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1034319756, COSV99964836; called by muse, mutect2, varscan2
- FGD1 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV64308518; called by muse, mutect2, varscan2
- FGF18 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs775745780, COSV51128736; called by muse, mutect2, varscan2
- FOXI1 | c.294C>A p.S98R | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs866622107, COSV100089284; called by muse, mutect2, varscan2
- GDNF | c.335G>T p.R112M | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV58478928; called by muse, mutect2, varscan2
- GIMAP8 | c.131C>G p.T44R | Missense Mutation (SNP) | VAF 115/506 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100217592; called by muse, mutect2, varscan2
- GPR50 | c.1003C>A p.L335M | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as COSV99506034; called by muse, mutect2, varscan2
- GRM8 | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 86/346 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.657); catalogued as rs761264012, COSV58873381; called by muse, mutect2, varscan2
- GUCY1B1 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV100025506, COSV52376201; called by muse, mutect2, varscan2
- HCCS | c.609-1G>A p.X203_splice | Splice Site (SNP) | VAF 50/264 reads (19%) | catalogued as rs868563341; called by muse, mutect2, varscan2
- HFM1 | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV54035205; called by muse, mutect2, varscan2
- HSPA4 | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 46/115 reads (40%) | catalogued as COSV100507668; called by muse, mutect2, varscan2
- IGF2BP1 | c.819G>T p.T273= | Splice Region (SNP) | VAF 54/182 reads (30%) | catalogued as COSV51729993; called by muse, varscan2
- KCNT2 | c.1705C>G p.Q569E | Missense Mutation (SNP) | VAF 124/307 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99652447; called by muse, varscan2
- KIF16B | c.3523G>C p.A1175P | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); catalogued as COSV61706691; called by muse, mutect2, varscan2
- KLHL38 | c.1202T>A p.M401K | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1193417841; called by muse, mutect2, varscan2
- KLK5 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 88/454 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV60450120; called by muse, mutect2, varscan2
- KMT2A | c.3461G>T p.R1154L | Missense Mutation (SNP) | VAF 94/394 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63286260, COSV63290453; called by muse, mutect2, varscan2
- KRT23 | c.307C>A p.R103S | Missense Mutation (SNP) | VAF 170/635 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV52928342; called by muse, mutect2, varscan2
- L1TD1 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV63133455; called by muse, mutect2, varscan2
- LAMA5 | c.9370G>T p.A3124S | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs377731667; called by muse, mutect2, varscan2
- LEPROT | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.712); catalogued as rs879134302; called by muse, mutect2, varscan2
- LEUTX | c.332A>G p.Y111C | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1266794429; called by muse, mutect2, varscan2
- LPAR3 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV65452614; called by muse, mutect2, varscan2
- LRP1B | c.12719G>C p.W4240S | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.996); catalogued as COSV67195157, COSV67198511; called by muse, mutect2
- LRP1B | c.1314G>T p.R438S | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV67187000, COSV67234204; called by muse, mutect2, varscan2
- LRRC53 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 26/147 reads (18%) | catalogued as rs1271863770, COSV53945976; called by muse, mutect2
- MAGEC1 | c.3085C>A p.R1029S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.234); catalogued as COSV53579765, COSV99596363; called by muse, mutect2, varscan2
- MAN2A1 | c.1897G>T p.D633Y | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV99072888; called by muse, mutect2, varscan2
- MECP2 | c.482G>C p.G161A | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as CM014899, CM066124; called by muse, mutect2, varscan2
- MUC16 | c.32888C>A p.P10963H | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.381); catalogued as rs374230290; called by muse, mutect2, varscan2
- MUC16 | c.8225G>T p.G2742V | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs538016442, COSV67457859; called by muse, mutect2, varscan2
- MXRA5 | c.6076G>T p.V2026L | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as rs375991615, COSV54237684; called by muse, mutect2, varscan2
- MYH1 | c.5741C>A p.A1914D | Missense Mutation (SNP) | VAF 77/441 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56854612; called by muse, mutect2, varscan2
- MYO1H | c.1410+2T>A p.X470_splice | Splice Site (SNP) | VAF 58/124 reads (47%) | catalogued as rs1282251813; called by muse, mutect2
- NAP1L3 | c.766C>G p.P256A | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.046); catalogued as COSV59074644; called by muse, mutect2, varscan2
- NECAB1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 147/428 reads (34%) | catalogued as COSV70238268; called by muse, varscan2
- NETO1 | c.472C>G p.P158A | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV55009842; called by muse, mutect2, varscan2
- NETO1 | c.471T>A p.D157E | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); catalogued as rs143129777; called by muse, mutect2, varscan2
- NLRP7 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 109/224 reads (49%) | catalogued as COSV60172849; called by muse, mutect2, varscan2
- NPSR1 | c.513G>C p.W171C | Missense Mutation (SNP) | VAF 114/448 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62199532, COSV62202467; called by muse, mutect2, varscan2
- OPA3 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 103/307 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs767889585; called by muse, mutect2, varscan2
- OPTC | c.141del p.N48Mfs*4 | Frame Shift Del (DEL) | VAF 448/1090 reads (41%) | catalogued as COSV100557853; called by mutect2, pindel, varscan2
- OR10G3 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs370817486, COSV57809639; called by muse, mutect2, varscan2
- OR10G8 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV70909061; called by muse, mutect2, varscan2
- OR14A2 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 147/374 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1177074636; called by muse, mutect2, varscan2
- OR2C3 | c.863C>A p.P288Q | Missense Mutation (SNP) | VAF 60/624 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV63574725; called by muse, mutect2
- OR3A1 | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs538476251; called by muse, mutect2, varscan2
- OR4Q3 | c.876C>G p.N292K | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV59179129; called by muse, mutect2, varscan2
- OR5T1 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.612); catalogued as COSV57303558; called by muse, mutect2, varscan2
- P2RX3 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.795); catalogued as COSV54443161; called by muse, mutect2, varscan2
- P2RX6 | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141213308; called by muse, mutect2, varscan2
- PCDH11X | c.277C>A p.R93S | Missense Mutation (SNP) | VAF 115/621 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53455530; called by muse, mutect2, varscan2
- PCDHA1 | c.1444G>C p.A482P | Missense Mutation (SNP) | VAF 146/608 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.017); catalogued as COSV65373411; called by muse, mutect2, varscan2
- PCDHA4 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 89/371 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); catalogued as rs17844284, COSV63540047; called by muse, mutect2, varscan2
- PCDHB4 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV52022541; called by muse, mutect2, varscan2
- PCDHGA3 | c.1879C>A p.R627S | Missense Mutation (SNP) | VAF 76/338 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.516); catalogued as rs62378406, COSV54056886; called by muse, mutect2, varscan2
- PCDHGB1 | c.1990C>A p.L664M | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV54058771; called by muse, mutect2, varscan2
- PIRT | c.157del p.R53Afs*27 | Frame Shift Del (DEL) | VAF 36/133 reads (27%) | catalogued as COSV74119916; called by mutect2, pindel, varscan2
- PKHD1L1 | c.8120C>A p.A2707D | Missense Mutation (SNP) | VAF 117/526 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV65736467; called by muse, mutect2, varscan2
- PLCB2 | c.3338G>T p.R1113L | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV53038485; called by muse, mutect2, varscan2
- PLP1 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as CM036008, COSV58275832; called by muse, mutect2, varscan2
- PLPP4 | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV100956524; called by muse, mutect2, varscan2
- POTEE | c.2573G>C p.G858A | Missense Mutation (SNP) | VAF 163/566 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100387885; called by muse, mutect2, varscan2
- PROKR2 | c.779C>A p.T260K | Missense Mutation (SNP) | VAF 68/462 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1010043; called by muse, mutect2, varscan2
- PRRC2C | c.2927G>C p.R976P (on ENST00000367742; = p.R974P on NM_015172.4) | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV100146325, COSV58915116; called by muse, mutect2
- PSG4 | c.1048C>T p.L350F | Missense Mutation (SNP) | VAF 116/256 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV54933049; called by muse, mutect2, varscan2
- PSMD8 | c.509A>T p.Q170L | Missense Mutation (SNP) | VAF 122/332 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs1157760903; called by muse, mutect2, varscan2
- PTPN5 | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62125707; called by muse, mutect2, varscan2
- PTPRD | c.2827G>A p.V943I | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100643465; called by muse, mutect2, varscan2
- PTPRZ1 | c.1488del p.N497Ifs*4 | Frame Shift Del (DEL) | VAF 50/204 reads (25%) | catalogued as COSV66435152; called by mutect2, pindel, varscan2
- RAB6D | c.418del p.E140Rfs*9 | Frame Shift Del (DEL) | VAF 264/664 reads (40%) | catalogued as COSV72151623; called by mutect2, varscan2
- RAPSN | c.1119_1121del p.K373del | In Frame Del (DEL) | VAF 7/39 reads (18%) | catalogued as rs759488854; called by pindel, varscan2
- RELN | c.8866A>G p.I2956V | Missense Mutation (SNP) | VAF 28/966 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs889941757, COSV59038169; called by muse, mutect2
- RETSAT | c.1096G>C p.G366R | Missense Mutation (SNP) | VAF 191/431 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs761237408; called by muse, mutect2, varscan2
- RHPN1 | c.1367G>T p.R456L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV56647117; called by muse, mutect2, varscan2
- RNF128 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 52/267 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV99048432; called by muse, mutect2, varscan2
- RSPH6A | c.1828C>G p.R610G | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99679777; called by muse, mutect2, varscan2
- SCML4 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.447); catalogued as COSV64633997; called by muse, mutect2, varscan2
- SEC24D | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 83/198 reads (42%) | catalogued as COSV54880901; called by muse, mutect2, varscan2
- SEC31B | c.1988G>T p.C663F | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64843713; called by muse, mutect2, varscan2
- SERPINB3 | c.1076C>A p.T359N | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs754315039, COSV99379516; called by muse, mutect2, varscan2
- SERTAD4 | c.435G>T p.M145I | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV65399210; called by muse, mutect2, varscan2
- SH2B2 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.259); catalogued as rs1012030336; called by muse, mutect2, varscan2
- SHANK1 | c.2914G>T p.G972W | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.844); catalogued as rs1374552020; called by muse, mutect2
- SIPA1L3 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs780595342; called by muse, mutect2, varscan2
- SLC38A11 | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 95/184 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773033642; called by muse, mutect2, varscan2
- SLC39A11 | c.108+1G>T p.X36_splice | Splice Site (SNP) | VAF 53/199 reads (27%) | catalogued as rs1282536313; called by muse, mutect2, varscan2
- SLC4A1 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 78/256 reads (30%) | catalogued as COSV99293619; called by muse, mutect2, varscan2
- SPEG | c.7823C>A p.A2608E | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56668129; called by muse, varscan2
- ST6GALNAC5 | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV59572560; called by muse, mutect2
- STARD8 | c.2732C>A p.T911N | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.925); catalogued as COSV52930508; called by muse, mutect2, varscan2
- TAF1L | c.3604G>C p.E1202Q | Missense Mutation (SNP) | VAF 138/455 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99643959; called by muse, mutect2, varscan2
- TCN1 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 82/526 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV57253107; called by muse, mutect2, varscan2
- TMEM132A | c.22C>A p.R8S | Missense Mutation (SNP) | VAF 97/280 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs745831135; called by muse, mutect2, varscan2
- TNFRSF13B | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0.031); catalogued as rs140914723; called by muse, mutect2, varscan2
- TNR | c.3475G>T p.E1159* | Nonsense Mutation (SNP) | VAF 189/451 reads (42%) | catalogued as COSV54883816; called by muse, mutect2, varscan2
- TRANK1 | c.6073G>T p.A2025S | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.531); catalogued as rs764342436; called by muse, mutect2, varscan2
- TRIP11 | c.3500G>T p.R1167L | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50915449; called by muse, mutect2, varscan2
- TRPM3 | c.2716C>A p.Q906K (on ENST00000357533 / NM_001366142.2; = p.Q749K on NM_020952.6) | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100677256, COSV62579625; called by muse, mutect2, varscan2
- TSHR | c.1422C>G p.D474E | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1472384664, BM1235128; called by muse, mutect2, varscan2
- TSHZ2 | c.2790C>A p.D930E | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV61586543; called by muse, mutect2, varscan2
- TUBA3C | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.7); catalogued as rs138384157, COSV68028168; called by muse, mutect2
- TUBA3C | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV67139094; called by muse, mutect2, varscan2
- TYRP1 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV66357764; called by muse, mutect2, varscan2
- ULK2 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 48/299 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755603472; called by muse, mutect2, varscan2
- USH2A | c.13812G>A p.R4604= | Splice Region (SNP) | VAF 32/346 reads (9%) | catalogued as rs961083405, COSV100244833; called by muse, mutect2
- WDFY4 | c.3235A>T p.S1079C | Missense Mutation (SNP) | VAF 146/563 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs904185325; called by muse, mutect2, varscan2
- WDR36 | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV72411524; called by muse, mutect2, varscan2
- WNT16 | c.820C>A p.Q274K (on ENST00000222462 / NM_057168.2; = p.Q264K on NM_016087.2) | Missense Mutation (SNP) | VAF 101/412 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.02); catalogued as rs753293526, COSV99742828; called by muse, mutect2, varscan2
- XIRP2 | c.3464C>A p.S1155Y (on ENST00000628543; = p.S1330Y on NM_152381.6) | Missense Mutation (SNP) | VAF 32/369 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99748968; called by muse, mutect2
- ZAN | c.4582C>T p.Q1528* | Nonsense Mutation (SNP) | VAF 58/157 reads (37%) | catalogued as rs1334277919; called by muse, mutect2, varscan2
- ZBBX | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV56786731; called by muse, varscan2
- ZBTB7C | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs758871407, COSV100134566; called by muse, mutect2, varscan2
- ZFAND4 | c.1300G>T p.G434W | Missense Mutation (SNP) | VAF 93/423 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV60859732; called by muse, mutect2, varscan2
- ZFP28 | c.68C>G p.T23R | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as rs1375706638; called by muse, mutect2, varscan2
- ZNF211 | c.848G>A p.R283K (on ENST00000347302 / NM_198855.4; = p.R296K on NM_006385.5) | Missense Mutation (SNP) | VAF 248/564 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV53741854, COSV99560268; called by muse, mutect2, varscan2
- ZNF335 | c.2416C>T p.R806W | Missense Mutation (SNP) | VAF 110/355 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762032120, COSV59819903; called by muse, mutect2, varscan2
- ZNF596 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 45/124 reads (36%) | catalogued as rs202032273; called by muse, mutect2, varscan2
- ZNF607 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 111/399 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV62206141; called by muse, mutect2, varscan2
- ZNF696 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 71/246 reads (29%) | catalogued as rs1258133607, COSV100350675; called by muse, mutect2, varscan2
- ZNF773 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as rs963246737, COSV99989570; called by muse, mutect2, varscan2
- ABCA6 | c.461-2A>T p.X154_splice | Splice Site (SNP) | VAF 103/406 reads (25%) | called by muse, mutect2, varscan2
- ABCB1 | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 153/590 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC11 | c.2140G>T p.G714* | Nonsense Mutation (SNP) | VAF 42/281 reads (15%) | called by muse, mutect2, varscan2
- AC069544.2 | c.643A>G p.M215V | Missense Mutation (SNP) | VAF 53/364 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACAN | c.233T>G p.V78G | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ACCS | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ACE2 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ACSL4 | c.43G>T p.V15F | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTN2 | c.1068C>A p.N356K | Missense Mutation (SNP) | VAF 91/706 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADAM2 | c.891+1G>T p.X297_splice | Splice Site (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- ADARB2 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ADCK5 | c.1727A>G p.Q576R | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADGRG2 | c.1973G>T p.R658M (on ENST00000379869 / NM_001079858.3; = p.R655M on NM_005756.4) | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRL3 | c.3342G>T p.M1114I (on ENST00000506720 / NM_001322402.2; = p.M1046I on NM_015236.6) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AEBP1 | c.1966C>A p.L656M | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AEBP1 | c.2885C>A p.P962Q | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- AEBP2 | c.1457dup p.L486Ffs*47 (on ENST00000398864 / NM_001114176.2; = p.L486Ffs*23 on NM_153207.5) | Frame Shift Ins (INS) | VAF 76/229 reads (33%) | called by mutect2, pindel, varscan2
- AGBL1 | c.2774G>T p.C925F | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AL133500.1 | c.1403C>A p.P468H | Missense Mutation (SNP) | VAF 76/379 reads (20%) | SIFT deleterious, low confidence (0.01); called by muse, varscan2
- AL133500.1 | c.1402C>A p.P468T | Missense Mutation (SNP) | VAF 76/378 reads (20%) | SIFT tolerated, low confidence (0.15); called by muse, varscan2
- AL139011.2 | c.521C>G p.T174R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | PolyPhen benign (0.001); called by muse, varscan2
- ANHX | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ANKFY1 | c.2558C>T p.A853V (on ENST00000341657 / NM_001330063.2; = p.A854V on NM_016376.5) | Missense Mutation (SNP) | VAF 75/326 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ANKK1 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 48/248 reads (19%) | called by muse, mutect2, varscan2
- ANKRD27 | c.2222G>T p.S741I | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ANKRD30A | c.1496C>A p.P499H (on ENST00000611781; = p.P443H on NM_052997.2) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ANKRD30A | c.2622del p.E875Rfs*23 (on ENST00000611781; = p.E819Rfs*23 on NM_052997.2) | Frame Shift Del (DEL) | VAF 82/764 reads (11%) | called by mutect2, pindel, varscan2
- ANO1 | c.533C>A p.T178K | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANO1 | c.898-1G>T p.X300_splice | Splice Site (SNP) | VAF 34/152 reads (22%) | called by muse, mutect2, varscan2
- ANOS1 | c.543T>A p.G181= | Splice Region (SNP) | VAF 68/427 reads (16%) | called by muse, mutect2, varscan2
- AR | c.1322C>G p.A441G | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ARHGAP21 | c.641T>A p.M214K | Missense Mutation (SNP) | VAF 142/557 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP23 | c.1837del p.L613Cfs*117 | Frame Shift Del (DEL) | VAF 47/187 reads (25%) | called by mutect2, pindel, varscan2
- ARMCX6 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 91/472 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ASMTL | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ASTN2 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATF7IP | c.3511G>T p.V1171F | Missense Mutation (SNP) | VAF 153/351 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATG14 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP6AP1 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- ATP6V1A | c.1020G>T p.M340I | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ATP8B3 | c.956G>C p.C319S | Missense Mutation (SNP) | VAF 115/222 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- B3GNT2 | c.1117A>T p.M373L | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- BARHL1 | c.428A>G p.K143R | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.283); called by muse, varscan2
- BCOR | c.1077G>T p.K359N | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCORL1 | c.3905C>A p.P1302H | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- BEGAIN | c.759C>A p.D253E | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- BLM | c.2303A>C p.E768A | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMP15 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BMP3 | c.778C>G p.Q260E | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- BPI | c.257G>T p.S86I (on ENST00000262865; = p.S82I on NM_001725.3) | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BPI | c.1102C>A p.P368T (on ENST00000262865; = p.P364T on NM_001725.3) | Missense Mutation (SNP) | VAF 93/349 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- BRD3 | c.1406A>T p.Q469L | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- BRSK1 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 49/393 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRSK2 | c.117C>G p.C39W | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- BTK | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTNL9 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C10orf120 | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- C10orf90 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- C2CD4C | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C2orf78 | c.1572G>T p.E524D | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- C3orf20 | c.1970C>G p.T657S | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CABP1 | c.749T>A p.L250Q (on ENST00000316803 / NM_001033677.1; = p.L47Q on NM_004276.5) | Missense Mutation (SNP) | VAF 171/321 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1E | c.5936C>A p.S1979Y | Missense Mutation (SNP) | VAF 151/306 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- CACNB1 | c.1644G>T p.W548C | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CACNG1 | c.645C>A p.C215* | Nonsense Mutation (SNP) | VAF 55/305 reads (18%) | called by muse, mutect2, varscan2
- CADPS | c.2458G>T p.V820F | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- CARD10 | c.2940G>T p.W980C | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CARTPT | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 81/365 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CASS4 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CBFA2T3 | c.1315A>T p.S439C | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CBLN4 | c.35C>A p.P12Q | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CCDC14 | c.855G>T p.L285F (on ENST00000488653; = p.L237F on NM_022757.5) | Missense Mutation (SNP) | VAF 111/422 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC14 | c.231G>T p.A77= (on ENST00000488653; = p.A29= on NM_022757.5) | Splice Region (SNP) | VAF 18/62 reads (29%) | called by muse, varscan2
- CCNJ | c.219C>A p.D73E | Missense Mutation (SNP) | VAF 44/402 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCR2 | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- CD19 | c.1091C>A p.A364D | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CD1A | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 66/628 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD300LF | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CDC14A | c.1207A>T p.K403* | Nonsense Mutation (SNP) | VAF 31/231 reads (13%) | called by muse, mutect2, varscan2
- CDCP1 | c.1645G>T p.V549L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- CDH18 | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 138/473 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); called by muse, varscan2
- CDH2 | c.2705_2716del p.G902_D905del | In Frame Del (DEL) | VAF 86/292 reads (29%) | called by pindel, varscan2
- CDH22 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- CDH8 | c.1101T>A p.S367R | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- CELA1 | c.269T>A p.V90E | Missense Mutation (SNP) | VAF 143/272 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CELSR3 | c.5156G>T p.C1719F | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CENPF | c.971A>T p.K324I | Missense Mutation (SNP) | VAF 50/494 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- CFAP74 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- CFC1 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 182/823 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- CHGB | c.50C>G p.A17G | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CHIT1 | c.473T>A p.L158Q | Missense Mutation (SNP) | VAF 68/469 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNA1 | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 101/724 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CHRNA9 | c.1116A>C p.K372N | Missense Mutation (SNP) | VAF 101/247 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CNBD1 | c.556T>A p.F186I | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNTNAP5 | c.1873G>T p.E625* | Nonsense Mutation (SNP) | VAF 20/142 reads (14%) | called by muse, mutect2, varscan2
- COL22A1 | c.4502C>T p.P1501L | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- COL4A2 | c.3919C>A p.P1307T | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- COL5A2 | c.4103G>T p.R1368I | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- COL5A2 | c.1825G>C p.G609R | Missense Mutation (SNP) | VAF 289/743 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPB2 | c.1304del p.G435Afs*10 | Frame Shift Del (DEL) | VAF 17/101 reads (17%) | called by mutect2, pindel, varscan2
- COQ4 | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CPNE1 | c.1174G>T p.A392S (on ENST00000352393; = p.A397S on NM_003915.5) | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CSF2RB | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CSMD3 | c.1942G>C p.G648R (on ENST00000297405 / NM_001363185.1; = p.G544R on NM_052900.3) | Missense Mutation (SNP) | VAF 54/520 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTAGE1 | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 31/194 reads (16%) | called by muse, mutect2, varscan2
- CTXN2 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP2C19 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, varscan2
- DCAF12L1 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF12L2 | c.1091C>A p.T364N | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCAF13 | c.999G>T p.W333C | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DCLK1 | c.1670A>T p.E557V | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DCP1B | c.1267G>T p.G423* | Nonsense Mutation (SNP) | VAF 151/295 reads (51%) | called by muse, mutect2, varscan2
- DDX59 | c.1613G>T p.R538I | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DEFB110 | c.105C>A p.C35* | Nonsense Mutation (SNP) | VAF 35/138 reads (25%) | called by muse, mutect2, varscan2
- DEFB116 | c.48C>G p.I16M | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DGKB | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DHX8 | c.3434A>T p.Q1145L | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- DIS3 | c.1546G>T p.G516* | Nonsense Mutation (SNP) | VAF 81/311 reads (26%) | called by muse, mutect2, varscan2
- DLGAP5 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- DNAH6 | c.3082G>T p.V1028L | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- DVL3 | c.1441G>T p.V481F | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYSF | c.3245A>C p.E1082A | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2
- EDEM3 | c.612+1G>A p.X204_splice | Splice Site (SNP) | VAF 44/98 reads (45%) | called by muse, varscan2
- EIF4E1B | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ELAVL4 | c.971A>T p.N324I | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- EML6 | c.3085G>T p.A1029S | Missense Mutation (SNP) | VAF 145/386 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- EP400 | c.9246G>T p.Q3082H | Missense Mutation (SNP) | VAF 151/260 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- EPB41L3 | c.2452A>T p.T818S | Missense Mutation (SNP) | VAF 97/295 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHA3 | c.1529G>T p.R510L | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPHA7 | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERCC2 | c.777_778del p.C259* | Nonsense Mutation (DEL) | VAF 71/282 reads (25%) | called by mutect2, pindel, varscan2
- ERVV-2 | c.112G>T p.G38* | Nonsense Mutation (SNP) | VAF 38/433 reads (9%) | called by muse, mutect2, varscan2
- ESS2 | c.304+1G>T p.X102_splice | Splice Site (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- FABP12 | c.246+1G>T p.X82_splice | Splice Site (SNP) | VAF 27/638 reads (4%) | called by muse, mutect2
- FAM120C | c.2741T>G p.V914G | Missense Mutation (SNP) | VAF 61/402 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.168); called by muse, mutect2
- FAM122C | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAM133A | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM180A | c.279C>A p.C93* | Nonsense Mutation (SNP) | VAF 74/321 reads (23%) | called by muse, mutect2, varscan2
- FAM216B | c.116A>G p.Q39R | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- FES | c.2253G>C p.W751C | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGG | c.503C>A p.T168K | Missense Mutation (SNP) | VAF 165/434 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- FHL1 | c.81C>G p.C27W | Missense Mutation (SNP) | VAF 54/347 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- FKBP7 | c.94A>C p.T32P | Missense Mutation (SNP) | VAF 106/747 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLT1 | c.3741C>A p.S1247R | Missense Mutation (SNP) | VAF 120/402 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- FMN2 | c.5081T>A p.V1694E | Missense Mutation (SNP) | VAF 148/350 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, varscan2
- FOXD4L3 | c.1243C>G p.R415G | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- FRG2C | c.156T>A p.S52R | Missense Mutation (SNP) | VAF 79/1522 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.062); called by muse, mutect2
- FRMPD4 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- FSCB | c.718G>C p.V240L | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FSIP2 | c.8927C>A p.T2976K | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- FXYD4 | c.17T>C p.L6P | Missense Mutation (SNP) | VAF 17/317 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.059); called by muse, mutect2
- GABRG2 | c.549G>T p.R183S | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- GABRG2 | c.758A>C p.Y253S (on ENST00000361925 / NM_001375343.1; = p.Y213S on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GATA1 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GATA5 | c.431C>G p.A144G | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- GLI3 | c.1984T>G p.S662A | Missense Mutation (SNP) | VAF 113/399 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR132 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR148 | c.970T>C p.Y324H | Missense Mutation (SNP) | VAF 98/348 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- GPR180 | c.687-2A>C p.X229_splice | Splice Site (SNP) | VAF 72/181 reads (40%) | called by muse, mutect2, varscan2
- GRIN3A | c.699G>T p.Q233H | Missense Mutation (SNP) | VAF 37/315 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- GRP | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GSDME | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 177/591 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- GZMB | c.417del p.Q140Rfs*24 | Frame Shift Del (DEL) | VAF 38/241 reads (16%) | called by mutect2, pindel, varscan2
- HAPLN4 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- HCCS | c.521+1G>T p.X174_splice | Splice Site (SNP) | VAF 47/309 reads (15%) | called by muse, mutect2, varscan2
- HIP1 | c.1936C>G p.P646A | Missense Mutation (SNP) | VAF 111/327 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- HKDC1 | c.1601G>C p.G534A | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLCS | c.1277A>T p.Y426F | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- HMCN1 | c.3883A>T p.K1295* | Nonsense Mutation (SNP) | VAF 15/173 reads (9%) | called by muse, mutect2
- HMCN1 | c.14176G>T p.G4726C | Missense Mutation (SNP) | VAF 438/861 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HMMR | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- HOXA6 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HOXB13 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HOXD13 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- HSP90AA1 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 69/220 reads (31%) | called by muse, varscan2
- HTR5A | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 132/493 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- HYDIN | c.12092C>G p.T4031R | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- IDH1 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 24/242 reads (10%) | called by muse, mutect2
- IFI16 | c.1712A>T p.D571V (on ENST00000295809 / NM_001364867.2; = p.D515V on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- IFNL3 | c.116T>A p.I39K | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- IFT172 | c.2755G>T p.A919S | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- IGF2R | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- IGFBP1 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGFL2 | c.310C>T p.H104Y (on ENST00000377693 / NM_001135113.2; = p.H115Y on NM_001002915.2) | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- IGHA2 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 71/449 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- IGHD | c.924G>T p.W308C | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-35 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 67/482 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- IGKV6-21 | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by mutect2, varscan2
- IGSF22 | c.2186del p.G729Efs*9 (on ENST00000319338; = p.G830Efs*9 on NM_173588.4) | Frame Shift Del (DEL) | VAF 26/166 reads (16%) | called by mutect2, pindel, varscan2
- IL1RAPL2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL37 | c.196del p.D66Ifs*13 | Frame Shift Del (DEL) | VAF 35/293 reads (12%) | called by mutect2, pindel, varscan2
- IMPDH1 | c.972G>A p.M324I (on ENST00000470772 / NM_001142573.2; = p.M410I on NM_000883.4) | Missense Mutation (SNP) | VAF 156/499 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSYN1 | c.820A>C p.K274Q | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS1 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQCG | c.322A>T p.K108* | Nonsense Mutation (SNP) | VAF 58/298 reads (19%) | called by muse, mutect2
- IRF2BP2 | c.1234A>T p.T412S | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); called by muse, mutect2
- IRF2BPL | c.1573G>T p.G525W | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.175); called by muse, mutect2
- ITGA8 | c.2302G>C p.D768H | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ITGB1 | c.266T>G p.I89R | Missense Mutation (SNP) | VAF 69/636 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ITGBL1 | c.812G>C p.C271S | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KBTBD8 | c.630A>C p.E210D | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KCND1 | c.1862G>A p.G621D | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KCNJ2 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 81/297 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KCNK13 | c.932G>T p.R311M | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- KEL | c.163T>A p.L55M | Missense Mutation (SNP) | VAF 111/438 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- KIAA0319L | c.675G>T p.K225N | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIAA0753 | c.95A>T p.N32I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- KIF21A | c.2903G>T p.R968M (on ENST00000361418 / NM_001378440.1; = p.R955M on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- KLHL1 | c.1619C>G p.S540* | Nonsense Mutation (SNP) | VAF 86/198 reads (43%) | called by mutect2, varscan2
- KLHL14 | c.678C>A p.D226E | Missense Mutation (SNP) | VAF 117/291 reads (40%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- KLHL30 | c.1409A>T p.H470L | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRT12 | c.1394C>A p.T465N | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by mutect2, varscan2
- KRTAP1-1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 211/850 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP3-1 | c.47C>A p.A16D | Missense Mutation (SNP) | VAF 79/263 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRTAP4-12 | c.479G>A p.C160Y | Missense Mutation (SNP) | VAF 68/498 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- KRTAP4-16 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated, low confidence (0.23); called by muse, mutect2, varscan2
- KRTAP4-16 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated, low confidence (0.2); called by muse, mutect2, varscan2
- LANCL2 | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 88/384 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- LRP4 | c.4951+2T>A p.X1651_splice | Splice Site (SNP) | VAF 79/453 reads (17%) | called by muse, mutect2, varscan2
- LRRC15 | c.1048A>T p.T350S | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- LRRC4B | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC7 | c.370A>G p.T124A (on ENST00000651989 / NM_001370785.2; = p.T91A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LY9 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 72/564 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- LYST | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 33/383 reads (9%) | called by muse, mutect2
- MAGEA1 | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEA6 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 93/446 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB18 | c.360G>C p.Q120H | Missense Mutation (SNP) | VAF 68/452 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MCIDAS | c.1095G>T p.Q365H | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- MDM1 | c.1306A>G p.I436V | Missense Mutation (SNP) | VAF 221/477 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MECP2 | c.633G>T p.R211S | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- MEFV | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 110/498 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEGF8 | c.4253C>T p.P1418L (on ENST00000251268 / NM_001271938.2; = p.P1351L on NM_001410.3) | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- MIA3 | c.5258del p.G1753Afs*19 | Frame Shift Del (DEL) | VAF 79/378 reads (21%) | called by mutect2, pindel, varscan2
- MMP16 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MOXD1 | c.1229T>C p.L410S | Missense Mutation (SNP) | VAF 104/261 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.035); called by muse, varscan2
- MPP6 | c.1600G>T p.V534F | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MRPL15 | c.369T>A p.N123K | Missense Mutation (SNP) | VAF 128/289 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MS4A14 | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MS4A14 | c.1828C>A p.P610T | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTHFD1 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 102/534 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTMR1 | c.1498A>T p.I500L | Missense Mutation (SNP) | VAF 67/398 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MTMR8 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- MTUS2 | c.1999C>A p.L667I | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- MUC17 | c.8308dup p.T2770Nfs*8 | Frame Shift Ins (INS) | VAF 18/137 reads (13%) | called by mutect2, pindel, varscan2
- MUC5AC | c.1003del p.Q336Rfs*125 | Frame Shift Del (DEL) | VAF 16/101 reads (16%) | called by mutect2, pindel, varscan2
- MUC5B | c.13889C>A p.P4630H | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- MXRA5 | c.561C>A p.H187Q | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYBL2 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- MYH13 | c.3365T>G p.L1122R | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MYO5A | c.3287A>T p.K1096M | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- NAALAD2 | c.1697T>C p.V566A | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NALCN | c.4604+1G>T p.X1535_splice | Splice Site (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- NAP1L2 | c.590T>A p.V197E | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.249); called by muse, varscan2
- NAPB | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- NAPB | c.162G>T p.M54I | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NAPSA | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAT8 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NBAS | c.6068del p.E2023Gfs*14 | Frame Shift Del (DEL) | VAF 124/368 reads (34%) | called by mutect2, pindel, varscan2
- NLGN1 | c.1646C>T p.T549I | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NLGN2 | c.506C>A p.T169K | Missense Mutation (SNP) | VAF 91/369 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NLRP10 | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- NMNAT3 | c.472G>T p.E158* (on ENST00000296202 / NM_001320512.1; = p.E121* on NM_178177.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 108/396 reads (27%) | called by muse, mutect2, varscan2
- NOS1 | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NOS2 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPC1L1 | c.150G>T p.M50I | Missense Mutation (SNP) | VAF 95/442 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRG3 | c.1792G>T p.V598L (on ENST00000404547 / NM_001370084.1; = p.V574L on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 162/556 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- NRK | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NUBP1 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 34/164 reads (21%) | called by muse, mutect2, varscan2
- NUCB2 | c.1087A>G p.K363E | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NUP160 | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- OBSL1 | c.5383G>A p.A1795T | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- OGDH | c.1687G>T p.D563Y | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OR14A2 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2AE1 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- OR5L2 | c.6del p.K3Rfs*21 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- OTOF | c.887del p.Y296Ffs*26 | Frame Shift Del (DEL) | VAF 138/406 reads (34%) | called by pindel, varscan2
- OTOG | c.2875G>T p.D959Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- OXCT1 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.863A>T p.Q288L (on ENST00000259318 / NM_001136562.3; = p.Q519L on NM_007203.5) | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- PANK2 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- PCDH11X | c.3367+1G>T p.X1123_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
- PCDH15 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 133/500 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PCDH19 | c.1283G>C p.G428A | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PCDHA13 | c.2645G>T p.G882V | Missense Mutation (SNP) | VAF 121/530 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHGB3 | c.1918C>T p.Q640* | Nonsense Mutation (SNP) | VAF 59/301 reads (20%) | called by muse, mutect2, varscan2
- PCNT | c.3499G>T p.G1167C | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PDE10A | c.2010G>A p.M670I | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PDE1B | c.42G>T p.E14D | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- PGR | c.1458C>A p.S486R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- PHF8 | c.2761C>A p.L921I (on ENST00000357988 / NM_001184896.1; = p.L885I on NM_015107.3) | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PHF8 | c.2749G>T p.A917S (on ENST00000357988 / NM_001184896.1; = p.A881S on NM_015107.3) | Missense Mutation (SNP) | VAF 65/333 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PHKA2 | c.3057G>C p.Q1019H | Missense Mutation (SNP) | VAF 78/374 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGQ | c.133G>T p.V45F | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLCXD3 | c.848A>G p.Q283R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); called by muse, mutect2
- PLEKHA2 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNA4 | c.3626G>A p.R1209K | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PLXNA4 | c.698C>A p.T233N | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNB3 | c.4139A>T p.K1380M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- POF1B | c.1075C>A p.L359I | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POU2F2 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.14); called by muse, mutect2
- POU5F1B | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 71/592 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R2B | c.354del p.E118Dfs*25 | Frame Shift Del (DEL) | VAF 92/593 reads (16%) | called by mutect2, pindel, varscan2
- PPP1R32 | c.931del p.E311Rfs*32 | Frame Shift Del (DEL) | VAF 73/242 reads (30%) | called by mutect2, pindel, varscan2
- PRDM9 | c.2228C>A p.T743K | Missense Mutation (SNP) | VAF 96/635 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); called by muse, varscan2
- PREX2 | c.3875del p.N1292Tfs*20 | Frame Shift Del (DEL) | VAF 163/650 reads (25%) | called by mutect2, pindel, varscan2
- PRKAA2 | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, varscan2
- PRKCG | c.1050C>A p.D350E | Missense Mutation (SNP) | VAF 68/485 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- PRPF4B | c.2717G>T p.G906V | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRUNE2 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PSAPL1 | c.1277G>A p.G426D | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- PSG7 | c.90del p.T32Pfs*52 | Frame Shift Del (DEL) | VAF 54/172 reads (31%) | called by mutect2, pindel
- PTH2R | c.1034G>A p.W345* | Nonsense Mutation (SNP) | VAF 100/322 reads (31%) | called by muse, mutect2, varscan2
- PTH2R | c.1035G>T p.W345C | Missense Mutation (SNP) | VAF 98/317 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTK2B | c.1802G>T p.R601L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- PTPRD | c.4148A>G p.K1383R | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB11FIP4 | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2
- RAB5A | c.163+1del | Frame Shift Del (DEL) | VAF 13/121 reads (11%) | called by mutect2, pindel
- RAD23B | c.497+1G>T p.X166_splice | Splice Site (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- RAI14 | c.2799G>C p.A933= | Splice Region (SNP) | VAF 15/107 reads (14%) | called by mutect2, varscan2
- RALGAPA2 | c.4191A>G p.I1397M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM20 | c.3452G>T p.G1151V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM20 | c.3649G>T p.G1217* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2
- RENBP | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- RESF1 | c.3430G>A p.V1144I | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- RFPL3 | c.274C>A p.P92T (on ENST00000249007 / NM_001098535.1; = p.P63T on NM_006604.2) | Missense Mutation (SNP) | VAF 93/258 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- RFXAP | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.242); called by muse, mutect2
- RGS12 | c.3824dup p.S1277Lfs*59 | Frame Shift Ins (INS) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- RIMS2 | c.1172C>T p.P391L (on ENST00000666250 / NM_001348490.2; = p.P199L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RNF150 | c.796A>G p.K266E | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- RNPEP | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNPEPL1 | c.1994T>A p.L665Q | Missense Mutation (SNP) | VAF 77/213 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ROBO3 | c.176C>A p.P59Q | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RPL14 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- RRM2 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- RSL24D1 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- RTCB | c.1435A>T p.T479S | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RYR1 | c.7532G>T p.G2511V | Missense Mutation (SNP) | VAF 137/351 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR2 | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, varscan2
- RYR3 | c.1098C>A p.Y366* | Nonsense Mutation (SNP) | VAF 32/158 reads (20%) | called by muse, mutect2, varscan2
- SACS | c.6259G>T p.E2087* | Nonsense Mutation (SNP) | VAF 35/231 reads (15%) | called by muse, mutect2, varscan2
- SALL2 | c.2093A>T p.K698M | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SALL4 | c.1279G>T p.V427L | Missense Mutation (SNP) | VAF 163/408 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SAMD9 | c.3301A>T p.N1101Y | Missense Mutation (SNP) | VAF 99/315 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SCG3 | c.677T>C p.I226T | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SCN10A | c.1316C>A p.T439K | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SCN1A | c.2079G>T p.R693S (on ENST00000303395 / NM_001202435.3; = p.R682S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/308 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SCN2A | c.5758C>T p.L1920F | Missense Mutation (SNP) | VAF 78/781 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SCN5A | c.2361C>G p.I787M | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- SCRN3 | c.584A>T p.K195M | Missense Mutation (SNP) | VAF 119/275 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCYL2 | c.1721T>G p.L574R | Missense Mutation (SNP) | VAF 94/202 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SELP | c.1074C>A p.Y358* | Nonsense Mutation (SNP) | VAF 277/594 reads (47%) | called by muse, mutect2, varscan2
- SEPHS1 | c.532A>T p.T178S | Missense Mutation (SNP) | VAF 71/546 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SGCE | c.77G>T p.S26I | Missense Mutation (SNP) | VAF 47/382 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- SH2D4B | c.576G>T p.W192C | Missense Mutation (SNP) | VAF 58/409 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SH3BP4 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 114/238 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SHANK3 | c.1569G>T p.M523I | Missense Mutation (SNP) | VAF 123/282 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- SHOX2 | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 56/462 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SHROOM4 | c.4291C>G p.R1431G | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHROOM4 | c.1598T>A p.L533H | Missense Mutation (SNP) | VAF 94/508 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SI | c.5227G>T p.V1743L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2
- SIM2 | c.205C>A p.R69S | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SKI | c.1077G>C p.L359F | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SLC35F6 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A15 | c.692G>T p.C231F | Missense Mutation (SNP) | VAF 236/557 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SLC7A7 | c.890C>A p.A297D | Missense Mutation (SNP) | VAF 95/522 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC8A2 | c.2212G>T p.A738S | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- SLCO5A1 | c.1471T>A p.Y491N | Missense Mutation (SNP) | VAF 49/530 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- SLCO5A1 | c.1047T>A p.S349R | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SLITRK2 | c.1026C>A p.S342R | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SMOX | c.804G>T p.Q268H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- SNRNP200 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 159/371 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SNX29 | c.1458G>T p.E486D | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SOCS1 | c.483G>T p.M161I | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPAG17 | c.5594G>T p.G1865V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, varscan2
- SPATA31E1 | c.4198A>T p.S1400C | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SPATC1L | c.546G>T p.E182D (on ENST00000291672 / NM_001142854.2; = p.E28D on NM_032261.5) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- SPDL1 | c.1604del p.L535Pfs*2 | Frame Shift Del (DEL) | VAF 38/250 reads (15%) | called by mutect2, pindel, varscan2
- SRMS | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 50/123 reads (41%) | called by muse, mutect2, varscan2
- SS18L1 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STARD7 | c.495C>A p.Y165* | Nonsense Mutation (SNP) | VAF 107/240 reads (45%) | called by muse, mutect2, varscan2
- STK39 | c.1242+1G>T p.X414_splice | Splice Site (SNP) | VAF 48/153 reads (31%) | called by muse, mutect2, varscan2
- TBC1D5 | c.525G>T p.Q175H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2
- TCP11X2 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 113/987 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- TEX13C | c.1676C>A p.P559H | Missense Mutation (SNP) | VAF 108/492 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); called by muse, varscan2
- TF | c.1672C>A p.P558T | Missense Mutation (SNP) | VAF 72/464 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THOC2 | c.4740G>T p.K1580N | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TMEM169 | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 100/795 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM174 | c.298T>A p.L100M | Missense Mutation (SNP) | VAF 161/748 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TMEM200B | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- TMEM200B | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- TMPRSS15 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- TNFRSF8 | c.777C>G p.C259W | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNIK | c.365del p.G122Vfs*4 | Frame Shift Del (DEL) | VAF 40/272 reads (15%) | called by mutect2, pindel, varscan2
- TNN | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 166/344 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNR | c.1303T>A p.W435R | Missense Mutation (SNP) | VAF 248/513 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOPBP1 | c.2209C>G p.L737V | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- TRGV3 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 144/532 reads (27%) | called by muse, mutect2, varscan2
- TRIM64B | c.728T>A p.L243Q | Missense Mutation (SNP) | VAF 86/900 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRO | c.3884C>A p.T1295N | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRPC4 | c.2537G>T p.G846V (on ENST00000379705 / NM_016179.4; = p.G851V on NM_003306.3) | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TRPV5 | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPV5 | c.1108C>G p.Q370E | Missense Mutation (SNP) | VAF 88/368 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TRPV5 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 141/486 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTC16 | c.126C>A p.F42L | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.63721G>T p.D21241Y (on ENST00000591111; = p.D13817Y on NM_003319.4) | Missense Mutation (SNP) | VAF 38/80 reads (48%) | PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- UBA2 | c.1288G>T p.V430L | Missense Mutation (SNP) | VAF 89/379 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- UBE2E3 | c.418A>T p.S140C | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- UBN2 | c.2719G>T p.A907S | Missense Mutation (SNP) | VAF 114/424 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- UNC80 | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 44/368 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- UNC93B1 | c.1769G>T p.G590V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- USH2A | c.13640A>T p.E4547V | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- USP19 | c.3044A>T p.D1015V | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- VAT1L | c.463T>C p.F155L | Missense Mutation (SNP) | VAF 96/476 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- VCAN | c.3479A>T p.H1160L | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- VCX3A | c.231C>A p.S77R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by mutect2, varscan2
- VPS13B | c.1590G>T p.M530I | Missense Mutation (SNP) | VAF 84/580 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WASHC5 | c.2218A>C p.K740Q | Missense Mutation (SNP) | VAF 290/727 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- WDR36 | c.1399A>T p.K467* | Nonsense Mutation (SNP) | VAF 69/529 reads (13%) | called by muse, mutect2
- WDR36 | c.1401G>T p.K467N | Missense Mutation (SNP) | VAF 68/532 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.05); called by muse, mutect2
- WHRN | c.2570A>G p.Q857R | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZBTB22 | c.354_359del p.M119_A120del | In Frame Del (DEL) | VAF 48/271 reads (18%) | called by mutect2, pindel, varscan2
- ZBTB34 | c.1247A>T p.E416V | Missense Mutation (SNP) | VAF 64/402 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZC3H12C | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZFAND1 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFHX4 | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 116/362 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZFP91 | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZNF107 | c.1757del p.G586Efs*15 | Frame Shift Del (DEL) | VAF 30/141 reads (21%) | called by mutect2, pindel, varscan2
- ZNF142 | c.464A>T p.Q155L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.102); called by muse, mutect2
- ZNF440 | c.53G>T p.W18L | Missense Mutation (SNP) | VAF 166/343 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF488 | c.278_285del p.T93Rfs*29 | Frame Shift Del (DEL) | VAF 79/376 reads (21%) | called by mutect2, pindel, varscan2
- ZNF511-PRAP1 | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF536 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF648 | c.596G>A p.W199* | Nonsense Mutation (SNP) | VAF 199/392 reads (51%) | called by muse, mutect2, varscan2
- ZNF705A | c.899G>T p.R300I | Missense Mutation (SNP) | VAF 122/279 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- ZNF773 | c.1198T>A p.S400T | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZSCAN5B | c.1120A>T p.R374W | Missense Mutation (SNP) | VAF 173/366 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCA12 | c.4629G>A p.L1543= (on ENST00000272895 / NM_173076.3; = p.L1225= on NM_015657.3) | Silent (SNP) | VAF 57/397 reads (14%) | catalogued as COSV55977229; called by muse, mutect2, varscan2
- ACACB | c.6846C>T p.R2282= | Silent (SNP) | VAF 54/385 reads (14%) | catalogued as rs1419599522; called by muse, mutect2, varscan2
- ADAM19 | c.1182G>A p.R394= | Silent (SNP) | VAF 52/212 reads (25%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.3843T>A p.S1281= | Silent (SNP) | VAF 59/416 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.3216C>A p.T1072= | Silent (SNP) | VAF 119/589 reads (20%) | catalogued as COSV61264599; called by muse, mutect2, varscan2
- ADCK2 | c.276C>T p.G92= | Silent (SNP) | VAF 47/153 reads (31%) | catalogued as rs560294528; called by muse, mutect2, varscan2
- ADGRB3 | c.4182T>C p.D1394= | Silent (SNP) | VAF 30/184 reads (16%) | catalogued as rs1188605114; called by muse, mutect2, varscan2
- ADGRG4 | c.2631G>A p.R877= | Silent (SNP) | VAF 24/137 reads (18%) | called by muse, mutect2, varscan2
- ADNP2 | c.1308G>T p.G436= | Silent (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- AKAIN1 | c.6G>T p.V2= | Silent (SNP) | VAF 51/339 reads (15%) | called by muse, mutect2, varscan2
- AMN | c.372A>T p.A124= | Silent (SNP) | VAF 47/249 reads (19%) | called by muse, mutect2, varscan2
- ARSD | c.930G>T p.T310= | Silent (SNP) | VAF 49/266 reads (18%) | called by muse, mutect2, varscan2
- ARSH | c.912G>T p.L304= | Silent (SNP) | VAF 87/407 reads (21%) | called by muse, mutect2, varscan2
- BCL9 | c.2299C>T p.L767= | Silent (SNP) | VAF 65/579 reads (11%) | called by muse, mutect2, varscan2
- BICRA | c.1047G>T p.T349= | Silent (SNP) | VAF 39/172 reads (23%) | catalogued as COSV67604858; called by muse, mutect2, varscan2
- BICRA | c.1290C>T p.T430= | Silent (SNP) | VAF 39/155 reads (25%) | called by muse, mutect2, varscan2
- BRINP1 | c.1068C>A p.I356= | Silent (SNP) | VAF 113/573 reads (20%) | catalogued as rs773056372, COSV56306566; called by muse, mutect2, varscan2
- BTNL9 | c.174G>A p.P58= | Silent (SNP) | VAF 69/231 reads (30%) | catalogued as rs138816460, COSV59793066; called by muse, mutect2, varscan2
- C6orf163 | c.648A>G p.E216= | Silent (SNP) | VAF 39/226 reads (17%) | called by muse, mutect2, varscan2
- CALD1 | c.999G>A p.E333= | Silent (SNP) | VAF 86/634 reads (14%) | catalogued as COSV62654534; called by muse, varscan2
- CAPN6 | c.1374G>A p.L458= | Silent (SNP) | VAF 132/595 reads (22%) | called by muse, mutect2, varscan2
- CASR | c.2550C>A p.P850= (on ENST00000490131; = p.P927= on NM_000388.4) | Silent (SNP) | VAF 47/141 reads (33%) | catalogued as COSV56134092, COSV99948591; called by muse, mutect2, varscan2
- CCDC127 | c.9C>T p.N3= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as rs1222650010; called by mutect2, varscan2
- CCDC88B | c.4218T>C p.S1406= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- CCNB3 | c.2436G>A p.K812= | Silent (SNP) | VAF 44/263 reads (17%) | catalogued as COSV52078436; called by muse, mutect2, varscan2
- CD1A | c.828G>T p.L276= | Silent (SNP) | VAF 32/235 reads (14%) | catalogued as COSV99192391; called by muse, mutect2, varscan2
- CDCP1 | c.1644G>T p.T548= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs774288213; called by muse, mutect2, varscan2
- CDH18 | c.705C>A p.V235= | Silent (SNP) | VAF 139/470 reads (30%) | called by muse, mutect2, varscan2
- CDH18 | c.537A>G p.L179= | Silent (SNP) | VAF 51/175 reads (29%) | catalogued as rs1350696152, COSV99932921; called by muse, mutect2, varscan2
- CDH22 | c.1056C>A p.P352= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100952848; called by muse, mutect2, varscan2
- CERK | c.12G>T p.T4= | Silent (SNP) | VAF 15/37 reads (41%) | called by mutect2, varscan2
- CHRD | c.2613C>T p.G871= | Silent (SNP) | VAF 34/205 reads (17%) | called by muse, mutect2, varscan2
- CLCN3 | c.813G>T p.L271= | Silent (SNP) | VAF 71/202 reads (35%) | called by muse, mutect2, varscan2
- CLVS2 | c.195C>T p.H65= | Silent (SNP) | VAF 112/275 reads (41%) | called by muse, mutect2, varscan2
- CNDP1 | c.1062C>A p.G354= | Silent (SNP) | VAF 29/198 reads (15%) | called by muse, mutect2, varscan2
- COL22A1 | c.672T>C p.P224= | Silent (SNP) | VAF 48/426 reads (11%) | called by muse, varscan2
- CPS1 | c.3123A>G p.L1041= | Silent (SNP) | VAF 146/365 reads (40%) | called by muse, mutect2, varscan2
- CSTF2 | c.6G>C p.A2= | Silent (SNP) | VAF 56/338 reads (17%) | called by muse, mutect2, varscan2
- CUL4B | c.2055C>A p.G685= | Silent (SNP) | VAF 36/265 reads (14%) | called by muse, mutect2, varscan2
- CYTH2 | c.69G>A p.R23= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as rs755558128; called by muse, mutect2, varscan2
- DCBLD1 | c.423G>A p.R141= | Silent (SNP) | VAF 45/143 reads (31%) | called by muse, mutect2, varscan2
- DISP3 | c.1113C>A p.A371= | Silent (SNP) | VAF 26/89 reads (29%) | called by muse, mutect2, varscan2
- DNAJB8 | c.408A>T p.A136= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as rs1238738307; called by muse, mutect2, varscan2
- DOCK10 | c.4089A>T p.P1363= | Silent (SNP) | VAF 26/258 reads (10%) | called by muse, mutect2, varscan2
- DOCK4 | c.3612C>T p.H1204= | Silent (SNP) | VAF 34/248 reads (14%) | called by muse, mutect2, varscan2
- DONSON | c.186G>T p.G62= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- DSC2 | c.2685A>T p.A895= | Silent (SNP) | VAF 47/387 reads (12%) | called by muse, mutect2, varscan2
- DTHD1 | c.438C>A p.S146= (on ENST00000456874; = p.S271= on NM_001170700.3) | Silent (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- DYTN | c.1035C>T p.T345= | Silent (SNP) | VAF 102/262 reads (39%) | called by muse, mutect2, varscan2
- DZIP1L | c.975C>T p.A325= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as rs1218930740; called by muse, mutect2, varscan2
- DZIP1L | c.456C>A p.T152= | Silent (SNP) | VAF 56/140 reads (40%) | called by muse, mutect2, varscan2
- EDA | c.318T>A p.L106= | Silent (SNP) | VAF 73/347 reads (21%) | called by muse, mutect2, varscan2
- EFCAB8 | c.456G>A p.K152= | Silent (SNP) | VAF 48/156 reads (31%) | called by muse, mutect2, varscan2
- EIF4G3 | c.210G>A p.A70= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs867464911, COSV63573095; called by mutect2, varscan2
- ELK1 | c.366C>A p.A122= | Silent (SNP) | VAF 59/265 reads (22%) | called by muse, mutect2, varscan2
- ENOX2 | c.675G>A p.E225= (on ENST00000338144 / NM_001382520.1; = p.E196= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 78/460 reads (17%) | catalogued as COSV57652245; called by muse, mutect2, varscan2
- ENY2 | c.63A>T p.I21= | Silent (SNP) | VAF 36/265 reads (14%) | called by muse, mutect2, varscan2
- EPHA5 | c.2028C>G p.T676= | Silent (SNP) | VAF 32/81 reads (40%) | called by muse, varscan2
- EXD2 | c.621G>T p.L207= (on ENST00000312994 / NM_001193362.1; = p.L82= on NM_018199.3) | Silent (SNP) | VAF 29/124 reads (23%) | called by muse, mutect2, varscan2
- FAAH2 | c.1201C>T p.L401= | Silent (SNP) | VAF 44/244 reads (18%) | called by muse, mutect2, varscan2
- FAM131B | c.228C>A p.A76= | Silent (SNP) | VAF 91/350 reads (26%) | called by muse, mutect2, varscan2
- FAM83G | c.822G>T p.T274= | Silent (SNP) | VAF 14/71 reads (20%) | called by muse, varscan2
- FCGBP | c.4941C>A p.G1647= | Silent (SNP) | VAF 65/447 reads (15%) | called by muse, mutect2, varscan2
- FGD5 | c.2559C>A p.I853= | Silent (SNP) | VAF 65/322 reads (20%) | called by mutect2, varscan2
- FLNA | c.3045G>T p.A1015= | Silent (SNP) | VAF 60/240 reads (25%) | called by muse, mutect2, varscan2
- FNDC4 | c.630G>A p.P210= | Silent (SNP) | VAF 44/340 reads (13%) | catalogued as rs1168718021; called by muse, mutect2, varscan2
- FOXD1 | c.1320C>A p.S440= | Silent (SNP) | VAF 107/428 reads (25%) | called by muse, mutect2, varscan2
- FOXE3 | c.276C>A p.L92= | Silent (SNP) | VAF 48/246 reads (20%) | called by muse, mutect2, varscan2
- FSCN3 | c.820C>A p.R274= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV50001186; called by muse, mutect2, varscan2
- GABRG3 | c.1353G>T p.T451= | Silent (SNP) | VAF 39/203 reads (19%) | called by muse, mutect2, varscan2
- GALNT14 | c.1221C>T p.I407= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as COSV61103226; called by muse, mutect2, varscan2
- GLDC | c.1224T>A p.A408= | Silent (SNP) | VAF 137/457 reads (30%) | called by muse, mutect2, varscan2
- GLT6D1 | c.21G>C p.L7= | Silent (SNP) | VAF 30/143 reads (21%) | called by muse, mutect2, varscan2
- GPR149 | c.723C>T p.T241= | Silent (SNP) | VAF 42/201 reads (21%) | catalogued as rs552356081; called by muse, mutect2, varscan2
- GSG1L2 | c.258G>T p.R86= | Silent (SNP) | VAF 62/228 reads (27%) | called by muse, mutect2, varscan2
- HK3 | c.2466C>T p.A822= | Silent (SNP) | VAF 29/141 reads (21%) | called by muse, mutect2, varscan2
- HNF4A | c.657G>T p.L219= | Silent (SNP) | VAF 116/468 reads (25%) | called by muse, mutect2, varscan2
- HYDIN | c.13947C>A p.I4649= | Silent (SNP) | VAF 42/708 reads (6%) | called by muse, mutect2
- IFNA16 | c.114G>A p.L38= | Silent (SNP) | VAF 99/388 reads (26%) | catalogued as COSV66509713; called by muse, mutect2, varscan2
- IGHMBP2 | c.2727G>T p.L909= | Silent (SNP) | VAF 139/314 reads (44%) | called by muse, mutect2, varscan2
- IGSF1 | c.1290G>C p.V430= | Silent (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2
- IL17RD | c.582A>T p.L194= | Silent (SNP) | VAF 70/243 reads (29%) | called by muse, mutect2, varscan2
- ITSN1 | c.2718G>T p.V906= | Silent (SNP) | VAF 32/146 reads (22%) | catalogued as COSV101180641; called by muse, mutect2, varscan2
- KCNH6 | c.411C>T p.A137= | Silent (SNP) | VAF 46/212 reads (22%) | catalogued as COSV100121204; called by muse, mutect2, varscan2
- KIF1A | c.1935G>T p.L645= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs779460275; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIF26B | c.3621C>A p.P1207= | Silent (SNP) | VAF 41/354 reads (12%) | called by muse, mutect2, varscan2
- KRT12 | c.1395C>A p.T465= | Silent (SNP) | VAF 60/276 reads (22%) | called by mutect2, varscan2
- KRT32 | c.576G>C p.R192= | Silent (SNP) | VAF 37/111 reads (33%) | called by muse, mutect2, varscan2
- KRT71 | c.153G>T p.L51= | Silent (SNP) | VAF 145/230 reads (63%) | catalogued as rs775856694, COSV57291963; called by muse, mutect2, varscan2
- LILRA5 | c.696G>A p.L232= | Silent (SNP) | VAF 114/469 reads (24%) | called by muse, mutect2, varscan2
- LPGAT1 | c.615A>T p.P205= | Silent (SNP) | VAF 60/506 reads (12%) | called by muse, mutect2, varscan2
- LRRN2 | c.93T>A p.P31= | Silent (SNP) | VAF 45/301 reads (15%) | called by muse, mutect2, varscan2
- MAT1A | c.942G>A p.V314= | Silent (SNP) | VAF 60/201 reads (30%) | called by muse, mutect2, varscan2
- MBL2 | c.141A>T p.P47= | Silent (SNP) | VAF 97/394 reads (25%) | called by muse, mutect2, varscan2
- MBOAT4 | c.982T>C p.L328= | Silent (SNP) | VAF 53/227 reads (23%) | called by muse, mutect2, varscan2
- MDGA2 | c.1870C>A p.R624= (on ENST00000399232 / NM_001113498.2; = p.R326= on NM_182830.4) | Silent (SNP) | VAF 89/311 reads (29%) | catalogued as rs762439461, COSV62090758, COSV62105078; called by muse, mutect2, varscan2
- MKLN1 | c.1497A>T p.S499= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as COSV61760152; called by muse, mutect2
- MLXIPL | c.627C>A p.G209= | Silent (SNP) | VAF 134/426 reads (31%) | called by muse, mutect2, varscan2
- MSLNL | c.99C>A p.P33= | Silent (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- MSS51 | c.465G>T p.V155= | Silent (SNP) | VAF 116/368 reads (32%) | called by muse, mutect2, varscan2
- MST1R | c.1776C>T p.S592= | Silent (SNP) | VAF 48/325 reads (15%) | called by muse, mutect2, varscan2
- MTMR1 | c.1497C>A p.P499= | Silent (SNP) | VAF 68/401 reads (17%) | called by muse, mutect2, varscan2
- MYH13 | c.3903G>T p.L1301= | Silent (SNP) | VAF 95/347 reads (27%) | called by muse, mutect2, varscan2
- MYH2 | c.1536G>A p.T512= | Silent (SNP) | VAF 136/824 reads (17%) | catalogued as rs146376676; called by muse, mutect2, varscan2
- MYOCD | c.2343C>T p.P781= | Silent (SNP) | VAF 55/404 reads (14%) | catalogued as COSV58499768; called by muse, mutect2, varscan2
- MYOG | c.207G>A p.A69= | Silent (SNP) | VAF 34/240 reads (14%) | catalogued as rs147554078; called by muse, mutect2, varscan2
- NLRP1 | c.795C>T p.S265= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as COSV52573820; called by muse, mutect2, varscan2
- NLRP14 | c.2214G>T p.G738= | Silent (SNP) | VAF 39/224 reads (17%) | catalogued as COSV55072271; called by muse, mutect2, varscan2
- NOS2 | c.2649A>G p.L883= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as rs1457127746; called by muse, mutect2, varscan2
- NPAP1 | c.1614C>A p.T538= | Silent (SNP) | VAF 52/179 reads (29%) | called by muse, mutect2, varscan2
- OR2T4 | c.24C>A p.A8= | Silent (SNP) | VAF 45/367 reads (12%) | called by muse, mutect2, varscan2
- OR4A15 | c.216T>A p.S72= | Silent (SNP) | VAF 71/373 reads (19%) | called by muse, mutect2, varscan2
- OR4C6 | c.336C>A p.L112= | Silent (SNP) | VAF 74/458 reads (16%) | catalogued as COSV58604497; called by muse, mutect2, varscan2
- OR51Q1 | c.177G>A p.Q59= | Silent (SNP) | VAF 45/203 reads (22%) | called by muse, mutect2, varscan2
- OTUD5 | c.1584C>A p.P528= | Silent (SNP) | VAF 37/211 reads (18%) | catalogued as COSV50235237; called by muse, mutect2, varscan2
- OTUD5 | c.102A>T p.G34= | Silent (SNP) | VAF 5/26 reads (19%) | called by mutect2, varscan2
- PAEP | c.441C>T p.D147= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as rs759775076, COSV99478997; called by muse, mutect2, varscan2
- PAMR1 | c.363C>T p.Y121= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as rs748163488, COSV53511749; called by muse, mutect2, varscan2
- PCDH15 | c.2061C>A p.I687= | Silent (SNP) | VAF 185/738 reads (25%) | catalogued as COSV57275184; called by muse, mutect2, varscan2
- PCDHGA2 | c.1326G>C p.V442= | Silent (SNP) | VAF 54/284 reads (19%) | catalogued as COSV54066287; called by muse, mutect2, varscan2
- PCDHGA6 | c.1743C>T p.S581= | Silent (SNP) | VAF 50/240 reads (21%) | catalogued as COSV53908205, COSV54055461; called by muse, mutect2, varscan2
- PCDHGA8 | c.1842G>T p.P614= | Silent (SNP) | VAF 44/279 reads (16%) | called by muse, mutect2, varscan2
- PDHA1 | c.501G>C p.V167= | Silent (SNP) | VAF 85/409 reads (21%) | called by muse, mutect2, varscan2
- PEG3 | c.2991T>A p.S997= | Silent (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2, varscan2
- PHLDB3 | c.909G>T p.G303= | Silent (SNP) | VAF 112/288 reads (39%) | called by muse, mutect2, varscan2
- PIEZO2 | c.4755C>A p.A1585= | Silent (SNP) | VAF 77/228 reads (34%) | called by muse, mutect2, varscan2
- POTEE | c.2574G>T p.G858= | Silent (SNP) | VAF 168/570 reads (29%) | catalogued as COSV100389392; called by muse, mutect2, varscan2
- POTEF | c.2526G>C p.L842= | Silent (SNP) | VAF 61/495 reads (12%) | catalogued as rs1235139574; called by muse, mutect2, varscan2
- PPP1R2B | c.27G>T p.R9= | Silent (SNP) | VAF 66/275 reads (24%) | called by muse, mutect2, varscan2
- PRPF19 | c.1219C>T p.L407= | Silent (SNP) | VAF 89/297 reads (30%) | catalogued as rs749686088, COSV57128342; called by muse, mutect2, varscan2
156 further variants in this file (0 protein-altering or splice-affecting, 46 silent, 110 other) are not listed here.
